Gene-level copy-number profile of tumor specimen ALCH-ABMP-TTP1-A from ALCHEMIST case ALCH-ABMP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 60.3 years (22,038 days).
Specimen ALCH-ABMP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61763cc5-19eb-4fec-8a15-60872ff2a98b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABMP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/d79177e5-85e8-4fdc-bd39-ac2cbaff9c22

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 11,356; copy number 2: 45,624; copy number 3: 1,759; copy number 5: 10; copy number 7: 30; copy number 8: 15; copy number 9: 17; copy number 11: 1; copy number 13: 10; copy number 14: 5; copy number 15: 4; copy number 16: 8; copy number 18: 11; copy number 22: 12.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,470,277–1,504,389, 1 gene: INTS1.
- chr14:103,694,516–103,733,668, 6 genes (within-gene range 0–1): AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA.
- chr16:1,493,344–1,510,457, 1 gene (within-gene range 0–2): TELO2.
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr16:2,268,155–2,274,691, 4 genes (within-gene range 0–2): AC009065.4, MIR3677, MIR940, MIR4717.
- chr16:88,651,935–88,663,161, 1 gene: MVD.
- chr21:43,919,795–43,919,901, 1 gene (within-gene range 0–1): RNU6-859P.
- chr21:44,978,832–45,004,727, 4 genes: AP001505.1, LINC00163, LINC00165, PICSAR.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,631,046–39,741,193, 5 genes, copy number 5: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5.
- chr12:63,844,700–64,162,217, 1 gene, copy number 14 (within-gene range 2–14): SRGAP1.
- chr12:63,878,787–64,130,539, 6 genes, copy number 9–14: AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2.
- chr12:64,404,392–65,121,305, 26 genes, copy number 7–13: XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P.
- chr12:65,169,583–65,248,355, 2 genes, copy number 7: LEMD3, AC026124.2.
- chr12:66,023,620–66,257,434, 12 genes, copy number 8: MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1.
- chr12:68,332,888–68,451,663, 1 gene, copy number 7 (within-gene range 2–7): LINC02384.
- chr12:68,426,331–70,243,379, 48 genes, copy number 7–22 (within-gene range 3–22): AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.
- chr12:70,515,870–70,637,440, 2 genes, copy number 7 (within-gene range 3–7): PTPRB, AC083809.1.
- chr12:71,007,773–72,186,618, 20 genes, copy number 5–9 (within-gene range 2–9): AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.

Autosomal genes at a single copy (total copy number 1): 8,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
